Somatic mutation profile of tumor specimen TCGA-EE-A2MD-06A (aliquot TCGA-EE-A2MD-06A-11D-A197-08) from TCGA case TCGA-EE-A2MD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.1 years (20,481 days).
Specimen TCGA-EE-A2MD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27a20063-e567-4f7a-92fb-f9527a4b5c15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MD-10A (Blood Derived Normal), aliquot TCGA-EE-A2MD-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b935235d-892d-48e2-875a-4eafc40e3fb5

The open-access MAF lists 2,018 somatic variants for this specimen: 1,292 protein-altering or splice-affecting, 682 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,170, Silent 682, Nonsense Mutation 76, Splice Region 22, Splice Site 17, Intron 17, RNA 17, Frame Shift Del 4, 3'UTR 3, 5'UTR 3, 5'Flank 2, In Frame Del 1.

Variants (750 of 2,018; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 30/104 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, varscan2
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 31/106 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, varscan2
- ASPM | c.7324C>T p.R2442* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as rs769364943, COSV54125310; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRIP1 | c.2493-1G>A p.X831_splice | Splice Site (SNP) | VAF 92/173 reads (53%) | catalogued as rs786203451, CS1512647, COSV52010278, COSV52010642, COSV99369411; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 46/99 reads (46%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- COL4A5 | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281874704, COSV60373840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.12617G>A p.W4206* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs372118787, COSV54239421; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.7981C>T p.R2661* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs149070832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH9 | c.7102G>A p.E2368K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs140313224, COSV52337194; called by muse, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 101/196 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs1021662947, CM165588, COSV55170971; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, mutect2, varscan2
- PTPRT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963254; called by mutect2, varscan2
- TTN | c.86112G>A p.W28704* (on ENST00000591111; = p.W21280* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 70/209 reads (33%) | catalogued as rs1559200525, COSV60392641; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV59393505; called by muse, mutect2, varscan2
- AADACL2 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62932743; called by muse, mutect2, varscan2
- AARS2 | c.1018T>A p.F340I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as COSV55117949; called by mutect2, varscan2
- ABCA12 | c.1268C>T p.P423L (on ENST00000272895 / NM_173076.3; = p.P105L on NM_015657.3) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1245953215, COSV55978418; called by muse, mutect2, varscan2
- ABCA13 | c.4474C>T p.L1492F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV70047845; called by muse, mutect2, varscan2
- ABCA3 | c.4066C>T p.P1356S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.743); catalogued as COSV57061044; called by muse, mutect2, varscan2
- ABCA4 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs779455131, COSV64678988; called by muse, mutect2, varscan2
- ABCC3 | c.4496G>A p.G1499E | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53330609; called by muse, mutect2, varscan2
- ABCC9 | c.2991G>A p.M997I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs1464981490, COSV53988496; called by mutect2, varscan2
- ABHD15 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56195049; called by muse, mutect2, varscan2
- AC109583.1 | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV58406792; called by muse, varscan2
- ACBD4 | c.677G>A p.W226* (on ENST00000376955 / NM_001378111.1; = p.L229= on NM_024722.4) | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV58853716; called by muse, mutect2, varscan2
- ACKR1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV63674709; called by muse, varscan2
- ACKR1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as COSV63674515; called by muse, varscan2
- ACOT11 | c.764+1G>A p.X255_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as rs761198115, COSV59346593; called by mutect2, varscan2
- ACP1 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs1222854326, COSV55242510; called by muse, varscan2
- ACSF2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV51974500; called by muse, mutect2, varscan2
- ACSM1 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54640781; called by muse, varscan2
- ACSS3 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759012460, COSV54086149; called by mutect2, varscan2
- ACTL6B | c.670-1G>A p.X224_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV50519823; called by muse, mutect2, varscan2
- ACTN2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs745651013, COSV63978680; called by muse, varscan2
- ADAM18 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55845273, COSV55856487; called by muse, mutect2, varscan2
- ADAM23 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52211747; called by muse, mutect2, varscan2
- ADAM28 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1340603323, COSV56106363; called by muse, mutect2, varscan2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- ADAM7 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51546382; called by muse, mutect2, varscan2
- ADAM7 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535001; called by muse, mutect2, varscan2
- ADAM7 | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1275917964, COSV51547463; called by muse, mutect2, varscan2
- ADAM8 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101291585, COSV69865041; called by mutect2, varscan2
- ADAMTS14 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV64607124; called by muse, mutect2, varscan2
- ADAMTS2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs146217716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS6 | c.2315G>A p.W772* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV66865430; called by muse, mutect2, varscan2
- ADAMTS6 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.239); catalogued as COSV66865432; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4052C>T p.S1351F | Missense Mutation (SNP) | VAF 110/140 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54447308; called by muse, mutect2, varscan2
- ADCY1 | c.2669G>A p.G890E | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52043810; called by muse, mutect2, varscan2
- ADCY8 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV53931311; called by muse, mutect2, varscan2
- ADCY8 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53931350; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347674535, COSV58444430; called by muse, mutect2, varscan2
- ADGRB3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.921); catalogued as rs745590202, COSV65385300; called by muse, mutect2, varscan2
- ADGRB3 | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as COSV53262751; called by muse, varscan2
- ADGRB3 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV53238942, COSV53247980; called by muse, mutect2, varscan2
- ADGRB3 | c.3915A>T p.E1305D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.978); catalogued as COSV53262770; called by muse, mutect2, varscan2
- ADGRF4 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV51958444; called by muse, mutect2, varscan2
- ADGRG4 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV54968890; called by muse, mutect2, varscan2
- ADGRG6 | c.2779G>A p.D927N | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV51602288; called by muse, mutect2, varscan2
- ADGRL2 | c.4330C>T p.P1444S (on ENST00000370717 / NM_001366005.1; = p.P1388S on NM_012302.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.271); catalogued as rs754139691, COSV54672643, COSV54692740; called by muse, mutect2, varscan2
- ADGRV1 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV101316079, COSV67996711; called by muse, mutect2, varscan2
- ADGRV1 | c.7358C>T p.S2453L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV67996713; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- ADIPOR1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61852652; called by muse, mutect2, varscan2
- AGO3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs779353364, COSV55797783; called by muse, mutect2, varscan2
- AHNAK | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs760834277, COSV57233893; called by muse, varscan2
- AKAP6 | c.6341C>T p.S2114F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55236119, COSV99797186; called by muse, mutect2, varscan2
- AKR1B10 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV62056786; called by muse, mutect2, varscan2
- AKR1C3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868935824, COSV101003185, COSV65911302; called by muse, varscan2
- ALDH2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs201835306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.1136A>G p.N379S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as COSV52523678; called by muse, mutect2, varscan2
- ALPK2 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV64490336; called by muse, mutect2, varscan2
- ALPK3 | c.3430C>T p.P1144S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as rs1187565301, COSV51941141; called by muse, mutect2, varscan2
- ALPP | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs781093591, COSV67398378; called by muse, mutect2, varscan2
- ALS2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1169584903, COSV51893665; called by muse, mutect2, varscan2
- AMBP | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs772743163, COSV54322765, COSV54325921; called by muse, mutect2, varscan2
- AMER3 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV58470840; called by mutect2, varscan2
- AMPD3 | c.1240G>A p.G414R (on ENST00000396553 / NM_001025389.2; = p.G423R on NM_000480.3) | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67332898; called by muse, varscan2
- ANGPT1 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52459245; called by muse, mutect2, varscan2
- ANGPT1 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs762090733, COSV52459254; called by muse, mutect2, varscan2
- ANK3 | c.6763C>T p.H2255Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as rs370076474; called by muse, mutect2, varscan2
- ANK3 | c.2671G>A p.E891K (on ENST00000280772 / NM_001320874.2; = p.E25K on NM_001149.3) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs753404464, COSV55062070, COSV99779502; called by muse, mutect2, varscan2
- ANKRD12 | c.2732A>C p.H911P | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50854268; called by muse, mutect2
- ANKRD16 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV51948951; called by muse, mutect2, varscan2
- ANKRD27 | c.2494C>A p.H832N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as COSV60136787; called by muse, mutect2, varscan2
- ANKRD30A | c.1939G>A p.E647K (on ENST00000611781; = p.E591K on NM_052997.2) | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV64623162; called by muse, mutect2, varscan2
- ANKRD30A | c.3136G>A p.E1046K (on ENST00000611781; = p.E990K on NM_052997.2) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV64623179; called by muse, mutect2, varscan2
- ANKRD30A | c.3550G>A p.E1184K (on ENST00000611781; = p.E1128K on NM_052997.2) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV64610842; called by muse, mutect2, varscan2
- ANKRD33 | c.428G>A p.G143E (on ENST00000340970 / NM_001304459.2; = p.G268E on NM_182608.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV56608802; called by muse, mutect2, varscan2
- ANKS4B | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV61140559; called by mutect2, varscan2
- ANXA9 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765434593, COSV64485688; called by mutect2, varscan2
- APOB | c.8965C>T p.Q2989* | Nonsense Mutation (SNP) | VAF 189/579 reads (33%) | catalogued as COSV51937341; called by muse, mutect2, varscan2
- APOBEC3C | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100815121; called by muse, mutect2, varscan2
- APOBR | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV60492385; called by mutect2, varscan2
- APOBR | c.2359G>A p.E787K (on ENST00000431282; = p.E796K on NM_018690.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs1468297033, COSV60494004; called by mutect2, varscan2
- APOL4 | c.484C>T p.P162S (on ENST00000352371 / NM_145660.2; = p.P159S on NM_030643.4) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1397545652, COSV60655527; called by muse, mutect2, varscan2
- ARAP2 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs531113400, COSV58293520; called by muse, mutect2, varscan2
- ARHGAP30 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as COSV63517467; called by muse, mutect2, varscan2
- ARHGAP36 | c.1377C>T p.I459= | Splice Region (SNP) | VAF 34/51 reads (67%) | catalogued as rs1436389659, COSV52272876, COSV99357677; called by muse, mutect2, varscan2
- ARHGAP5 | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.937); catalogued as COSV100565333, COSV61539724; called by muse, mutect2, varscan2
- ARHGEF19 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV54616953; called by muse, mutect2, varscan2
- ARL6IP1 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV58615051; called by muse, mutect2, varscan2
- ARMC4 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV53469039; called by muse, mutect2, varscan2
- ARMC8 | c.613C>T p.R205* (on ENST00000469044 / NM_001363941.2; = p.R191* on NM_014154.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/451 reads (27%) | catalogued as COSV61768099, COSV61768553; called by muse, mutect2, varscan2
- ARPP21 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51800743; called by muse, varscan2
- ART3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV61916503; called by muse, mutect2, varscan2
- ASB5 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56668428; called by muse, mutect2, varscan2
- ASIC1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV57320571; called by muse, mutect2, varscan2
- ASIC5 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV72233180; called by muse, mutect2, varscan2
- ASNS | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV51556585; called by muse, mutect2, varscan2
- ASPA | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV53983047; called by muse, varscan2
- ASTN1 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs199599422, COSV56088734; called by muse, mutect2, varscan2
- ASXL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52478934; called by muse, mutect2, varscan2
- ASXL3 | c.3955G>A p.D1319N | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV52471720, COSV52481925; called by muse, mutect2, varscan2
- ATAD2B | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53206671; called by muse, mutect2, varscan2
- ATP10A | c.3674C>T p.T1225I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV63525998; called by muse, mutect2, varscan2
- ATP10D | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV56714002; called by muse, mutect2, varscan2
- ATP13A4 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV55069302; called by muse, mutect2
- ATP13A5 | c.2186T>C p.V729A | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs895132442, COSV60868294; called by muse, mutect2, varscan2
- ATP1A2 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63406267; called by muse, mutect2, varscan2
- ATP8B4 | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52714450; called by muse, mutect2, varscan2
- AUTS2 | c.3314C>T p.S1105L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV61433235; called by mutect2, varscan2
- AXDND1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62649980; called by muse, mutect2, varscan2
- AXDND1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV62648508; called by muse, mutect2, varscan2
- AZGP1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52799746; called by muse, varscan2
- B3GALT1 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.295); catalogued as COSV59910118; called by muse, mutect2, varscan2
- B3GNT4 | c.67-1G>A p.X23_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99928042; called by muse, mutect2, varscan2
- B3GNT4 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV99928043; called by muse, mutect2, varscan2
- B4GALNT3 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as COSV56758781; called by muse, mutect2, varscan2
- B4GALNT4 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs761242637, COSV57322330; called by mutect2, varscan2
- BCAN | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100227894; called by muse, varscan2
- BCAS3 | c.1990G>A p.E664K (on ENST00000390652 / NM_001353144.2; = p.E649K on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66783426; called by muse, mutect2, varscan2
- BCL11A | c.982C>T p.P328S (on ENST00000335712 / NM_001365609.1; = p.P362S on NM_018014.4) | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1184263756, COSV59638521; called by muse, mutect2, varscan2
- BCL2L11 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs762820125, COSV100427184; called by mutect2, varscan2
- BCL2L11 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs375839187, COSV100427191; called by mutect2, varscan2
- BIN3 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs1401288184, COSV52386806, COSV99374119; called by muse, mutect2, varscan2
- BMP10 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as COSV54894285; called by muse, mutect2, varscan2
- BNC2 | c.743T>A p.F248Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66158780; called by mutect2, varscan2
- BRAT1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145047426; called by muse, mutect2, varscan2
- BRD8 | c.1372C>T p.P458S (on ENST00000254900 / NM_139199.2; = p.P531S on NM_006696.4) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV50174079; called by muse, mutect2, varscan2
- BRDT | c.965T>A p.I322N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62868068; called by muse, mutect2, varscan2
- BTBD11 | c.1810G>A p.G604S (on ENST00000280758 / NM_001018072.2; = p.G141S on NM_001017523.2) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55039611; called by muse, mutect2, varscan2
- BTBD9 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756222374, COSV58437337; called by muse, mutect2, varscan2
- BTN1A1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs1373788303, COSV55069997; called by muse, mutect2, varscan2
- BTN1A1 | c.1132A>T p.N378Y | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55070010; called by muse, mutect2, varscan2
- C10orf120 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as COSV100271547; called by muse, mutect2, varscan2
- C12orf40 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61138403; called by muse, mutect2, varscan2
- C16orf92 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV54228206, COSV54228303; called by mutect2, varscan2
- C1QTNF9 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59658335; called by muse, mutect2, varscan2
- C2orf16 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs754428308, COSV62673723; called by muse, mutect2, varscan2
- C3 | c.4280G>A p.R1427K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV55582537; called by muse, mutect2, varscan2
- C4BPA | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as COSV65537892; called by muse, mutect2, varscan2
- C6orf58 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV61666318; called by muse, mutect2, varscan2
- C7 | c.1663T>C p.L555= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57475343; called by muse, mutect2, varscan2
- C8orf37 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 175/579 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750509315, COSV54414046; called by muse, mutect2, varscan2
- CA8 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV58774244; called by muse, mutect2, varscan2
- CACNA1C | c.3148C>T p.L1050F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59780286; called by muse, mutect2
- CACNA1E | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV62433708; called by muse, varscan2
- CACNA2D4 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV54961992; called by muse, mutect2, varscan2
- CAMK1G | c.1338A>T p.K446N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.058); catalogued as rs929956229, COSV99151641; called by muse, mutect2, varscan2
- CAMK1G | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as rs775482310, COSV99151642; called by mutect2, varscan2
- CAMSAP2 | c.2432C>T p.P811L (on ENST00000236925 / NM_001297707.2; = p.P800L on NM_203459.3) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52678770; called by muse, mutect2, varscan2
- CAMTA1 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57884234; called by muse, mutect2, varscan2
- CANT1 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as COSV56605339; called by muse, mutect2, varscan2
- CAPSL | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV68439714; called by muse, mutect2, varscan2
- CAPSL | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV68439722; called by muse, mutect2, varscan2
- CARS1 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as COSV53461490; called by muse, varscan2
- CASP8AP2 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52750380; called by mutect2, varscan2
- CASR | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56141993; called by muse, mutect2, varscan2
- CASTOR1 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57577323; called by muse, mutect2, varscan2
- CATSPERB | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773719104, COSV56430819; called by muse, mutect2, varscan2
- CATSPERG | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53046736, COSV53054516; called by muse, mutect2, varscan2
- CAVIN2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs933479342, COSV58424270; called by mutect2, varscan2
- CBLL1 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as COSV56031024; called by muse, varscan2
- CBX7 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.335); catalogued as COSV99333967; called by muse, mutect2, varscan2
- CCBE1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67950008; called by muse, mutect2, varscan2
- CCDC116 | c.209T>C p.F70S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53038888; called by muse, mutect2, varscan2
- CCDC146 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53555550; called by mutect2, varscan2
- CCDC186 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV65162276; called by muse, mutect2, varscan2
- CCDC62 | c.540T>A p.C180* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV53437647; called by muse, mutect2, varscan2
- CCDC63 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV57531684; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, varscan2
- CD163L1 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100550420, COSV58025962; called by muse, mutect2, varscan2
- CD163L1 | c.1403G>A p.C468Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100549908, COSV58025973; called by mutect2, varscan2
- CD164L2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100927575; called by muse, varscan2
- CD177 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV65122787; called by muse, mutect2, varscan2
- CD300A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754986019, COSV60409512; called by muse, mutect2, varscan2
- CD86 | c.744G>A p.W248* (on ENST00000330540 / NM_175862.5; = p.W242* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV52605989; called by muse, mutect2, varscan2
- CD96 | c.631C>T p.H211Y (on ENST00000283285 / NM_198196.3; = p.H195Y on NM_005816.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs759301469, COSV51924014; called by muse, mutect2, varscan2
- CDH10 | c.2048A>G p.E683G | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1373368879, COSV52579594, COSV52600990; called by muse, mutect2, varscan2
- CDH10 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV52569365; called by muse, mutect2, varscan2
- CDK13 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 139/434 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51707424; called by muse, mutect2, varscan2
- CDK18 | c.913G>A p.E305K (on ENST00000506784 / NM_212503.3; = p.E275K on NM_002596.4) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV63729083; called by mutect2, varscan2
- CDK3 | c.192C>T p.V64= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as rs150589656; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3547G>C p.V1183L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62578043; called by muse, mutect2
- CDKL5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 140/207 reads (68%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV66113766; called by muse, mutect2, varscan2
- CEACAM5 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.784); catalogued as COSV55750352; called by mutect2, varscan2
- CECR2 | c.3713C>T p.P1238L (on ENST00000342247 / NM_001290047.2; = p.P1054L on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs770624477, COSV52849540; called by muse, mutect2, varscan2
- CENPQ | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV59922594; called by muse, mutect2, varscan2
- CEP350 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs376245955; called by muse, mutect2, varscan2
- CEP44 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV56659523; called by muse, mutect2, varscan2
- CES5A | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as rs376005485; called by muse, mutect2, varscan2
- CFAP20DC | c.2309C>T p.S770F (on ENST00000482387 / NM_001351530.2; = p.S519F on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99918144; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.073); catalogued as rs1206228775, COSV55829972; called by mutect2, varscan2
- CFAP299 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs142731425; called by mutect2, varscan2
- CFAP47 | c.2584G>A p.G862S | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV52892773; called by muse, mutect2, varscan2
- CFAP54 | c.5672G>A p.R1891Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs367592020; called by mutect2, varscan2
- CFAP54 | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV61571495, COSV61575925; called by muse, mutect2, varscan2
- CFAP54 | c.6664G>A p.E2222K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV61575928; called by muse, mutect2, varscan2
- CFAP65 | c.4421C>T p.S1474F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs780881070, COSV58567049; called by muse, mutect2, varscan2
- CFHR2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753517273, COSV66380522; called by muse, mutect2, varscan2
- CFLAR | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.604); catalogued as COSV57939187; called by muse, mutect2, varscan2
- CHAD | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV51974493; called by muse, mutect2, varscan2
- CHD4 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as rs138912992, COSV58912264; called by muse, varscan2
- CHST9 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52450851; called by muse, mutect2, varscan2
- CHTOP | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64155634; called by muse, mutect2, varscan2
- CIC | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1284125732, COSV50555566; called by muse, mutect2, varscan2
- CKAP2 | c.1907C>T p.S636F (on ENST00000378037 / NM_001098525.2; = p.S635F on NM_018204.5) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.66); catalogued as COSV51625105; called by muse, varscan2
- CLEC4M | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99940374; called by muse, varscan2
- CLEC4M | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940381; called by muse, varscan2
- CLUL1 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV58112093, COSV58113761; called by mutect2, varscan2
- CNBD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV72917666; called by muse, mutect2, varscan2
- CNBD2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV62588128; called by muse, mutect2, varscan2
- CNDP1 | c.759G>C p.V253= | Splice Region (SNP) | VAF 25/92 reads (27%) | catalogued as COSV62595605; called by muse, mutect2, varscan2
- CNGB3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60699721; called by muse, mutect2, varscan2
- CNR1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.367); catalogued as COSV62988046, COSV62989058; called by muse, mutect2, varscan2
- CNTN2 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959574033, COSV59347981; called by muse, mutect2, varscan2
- CNTN3 | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV55186372; called by muse, mutect2, varscan2
- CNTNAP4 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450320927, COSV56678851, COSV56703566; called by muse, mutect2, varscan2
- CNTRL | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV53054414; called by muse, mutect2, varscan2
- COBL | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54360622; called by muse, mutect2, varscan2
- COBLL1 | c.3076C>T p.P1026S (on ENST00000392717; = p.P988S on NM_014900.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1221402579, COSV52072407; called by muse, mutect2, varscan2
- COL11A1 | c.4840C>T p.H1614Y | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV62182412, COSV62199468; called by muse, varscan2
- COL11A2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV59495615, COSV59503453; called by muse, mutect2, varscan2
- COL14A1 | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV52853371; called by muse, mutect2, varscan2
- COL21A1 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.36); catalogued as COSV55182404; called by muse, mutect2, varscan2
- COL5A2 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as COSV66414079; called by muse, mutect2, varscan2
- COL5A3 | c.3038G>A p.G1013D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374930795, COSV99318290; called by muse, mutect2, varscan2
- COL6A1 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.07); catalogued as rs983326119, COSV62616066; called by muse, mutect2, varscan2
- COL6A3 | c.3793G>A p.G1265S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV55113645; called by muse, mutect2, varscan2
- COL6A3 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV55113675; called by muse, mutect2, varscan2
- COL6A6 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.939); catalogued as COSV62018544; called by muse, mutect2, varscan2
- COL7A1 | c.5135G>A p.G1712E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.782); catalogued as COSV60401989, COSV60404152; called by muse, mutect2, varscan2
- COL8A1 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729831, COSV53743896; called by muse, mutect2, varscan2
- COLEC10 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs868146062, COSV60523130; called by muse, varscan2
- COLGALT2 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62300918; called by muse, mutect2, varscan2
- COPS5 | c.574-1G>A p.X192_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100770025, COSV63474989; called by muse, mutect2, varscan2
- CORIN | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046263917, COSV56685078; called by mutect2, varscan2
- CORO2A | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs773618810, COSV59663934; called by mutect2, varscan2
- CPED1 | c.2310G>A p.K770= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60014593; called by muse, mutect2, varscan2
- CPQ | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375182115, COSV55163246; called by muse, mutect2, varscan2
- CPSF7 | c.845C>T p.P282L (on ENST00000394888 / NM_001136040.4; = p.P325L on NM_024811.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61213038, COSV61213177; called by muse, mutect2, varscan2
- CR1 | c.4174C>T p.R1392C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs766544117, COSV65457250; called by muse, mutect2, varscan2
- CR1L | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.949); catalogued as COSV54322549, COSV54326380; called by muse, varscan2
- CRACDL | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101194012; called by muse, mutect2, varscan2
- CRAT | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58879390; called by muse, mutect2, varscan2
- CRAT | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV100533947; called by muse, varscan2
- CREBBP | c.5399G>A p.R1800Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52118603, COSV52133512; called by muse, mutect2, varscan2
- CRYGC | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52205126, COSV52206252; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSF3R | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100117384; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by mutect2, varscan2
- CSMD2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV53970927; called by muse, mutect2, varscan2
- CSMD3 | c.5906T>A p.I1969N (on ENST00000297405 / NM_001363185.1; = p.I1865N on NM_052900.3) | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52340724; called by muse, mutect2, varscan2
- CSMD3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52164534; called by muse, mutect2, varscan2
- CSPG4 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as rs367600030; called by muse, varscan2
- CTAG2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs781895845, COSV55997023; called by muse, mutect2, varscan2
- CTNNAL1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.433); catalogued as COSV57701348, COSV57705922; called by muse, mutect2, varscan2
- CTR9 | c.3044C>T p.S1015L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100797544, COSV63729844; called by muse, mutect2, varscan2
- CTSS | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV64567214; called by mutect2, varscan2
- CUL9 | c.4945C>T p.L1649F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52735881; called by muse, mutect2, varscan2
- CUZD1 | c.1676A>G p.E559G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59028427; called by muse, mutect2, varscan2
- CWH43 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV56944723; called by muse, varscan2
- CXCL3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1018910984, COSV56018152; called by muse, mutect2, varscan2
- CYCS | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV59873124; called by muse, mutect2, varscan2
- CYLC2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.327); catalogued as rs1445690327, COSV66337146; called by muse, mutect2, varscan2
- CYP2C18 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.404); catalogued as COSV53675601; called by muse, mutect2, varscan2
- CYP4F12 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV61176591; called by muse, mutect2, varscan2
- CYP4F3 | c.-1G>A | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as rs750245246, COSV55414213; called by muse, mutect2, varscan2
- CYP4F8 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV57855107; called by muse, mutect2, varscan2
- CYSLTR1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV64821420; called by muse, varscan2
- DAB1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867818927, COSV59738855; called by muse, mutect2, varscan2
- DAPK2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774205620, COSV56048948; called by muse, mutect2, varscan2
- DBX2 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60340051; called by muse, mutect2, varscan2
- DCC | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV59141542; called by muse, mutect2, varscan2
- DCLK1 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV55214671; called by muse, varscan2
- DCLRE1C | c.1666G>A p.D556N (on ENST00000378278 / NM_001350965.2; = p.D441N on NM_022487.4) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV57953284, COSV57955838; called by muse, mutect2, varscan2
- DDX17 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53250002; called by muse, mutect2, varscan2
- DDX4 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61757665; called by muse, mutect2, varscan2
- DDX43 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV64838083; called by muse, mutect2, varscan2
- DENND6A | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as rs1430255909, COSV60768050; called by muse, mutect2, varscan2
- DHX38 | c.3325G>A p.G1109R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51701355; called by muse, mutect2, varscan2
- DIAPH1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220362809, COSV53889456; called by mutect2, varscan2
- DIP2B | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56593382; called by mutect2, varscan2
- DLGAP1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV59794026; called by muse, mutect2, varscan2
- DLGAP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747744035, COSV70103813; called by muse, mutect2, varscan2
- DLK1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.21); catalogued as rs759069385, COSV57993696; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DMBX1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs753300142, COSV63602670; called by muse, varscan2
- DMRT1 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV66524989; called by muse, mutect2, varscan2
- DMXL1 | c.2923T>A p.S975T | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100223465, COSV60722436; called by muse, mutect2, varscan2
- DNAH11 | c.7331C>T p.P2444L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552235699, COSV60949954; called by mutect2, varscan2
- DNAH11 | c.9748G>A p.D3250N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.975); catalogued as COSV60985766; called by muse, mutect2, varscan2
- DNAH17 | c.12751G>A p.E4251K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1288484034, COSV53147172, COSV53149133; called by muse, mutect2, varscan2
- DNAH17 | c.9217C>T p.L3073F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778368163, COSV67762140; called by muse, mutect2, varscan2
- DNAH17 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1279490855, COSV67757874; called by muse, varscan2
- DNAH17 | c.4546G>A p.D1516N | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1268863358, COSV67761463, COSV67762149; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.9293G>A p.R3098K | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54256685; called by muse, mutect2, varscan2
- DNAH5 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV54204246; called by muse, varscan2
- DNAH8 | c.2007G>A p.M669I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59471216; called by muse, mutect2, varscan2
- DNAH8 | c.13108G>A p.G4370S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757948242, COSV59485012; called by muse, mutect2, varscan2
- DNER | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV59178380; called by muse, mutect2, varscan2
- DNMT1 | c.4589C>T p.P1530L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61580828; called by muse, varscan2
- DNMT3A | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs777500092, COSV99259811; called by muse, varscan2
- DNMT3A | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV99259815; called by muse, varscan2
- DOP1B | c.5771C>T p.P1924L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749031776, COSV67696807; called by muse, mutect2, varscan2
- DPYD | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV60075134; called by muse, mutect2, varscan2
- DSC3 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64575858; called by muse, mutect2, varscan2
- DSG2 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV55198430, COSV99853037; called by muse, mutect2, varscan2
- DSG4 | c.2074-1G>A p.X692_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57397696; called by muse, mutect2, varscan2
- DSG4 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57398668; called by muse, mutect2, varscan2
- DSP | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs141834182; ClinVar: uncertain significance; called by mutect2, varscan2
- DSP | c.3739C>T p.R1247* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as rs1413961070, COSV65796670; called by muse, mutect2, varscan2
- DSP | c.5922G>T p.K1974N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs193059393, COSV101131537, COSV65796674; called by mutect2, varscan2
- DSPP | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as rs1335646735, COSV56817416, COSV99218262; called by muse, mutect2, varscan2
- DTX3L | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV56145877; called by muse, mutect2, varscan2
- DUSP10 | c.1372T>C p.F458L | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV60460023; called by muse, mutect2, varscan2
- DYNAP | c.283G>A p.E95K (on ENST00000321600; = p.E69K on NM_173629.3) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV58667425; called by muse, varscan2
- DYNLRB2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751931828, COSV58416178; called by mutect2, varscan2
- E2F1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55778942; called by muse, mutect2, varscan2
- ECE1 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs903413799, COSV51671402; called by mutect2, varscan2
- ECPAS | c.4153C>T p.P1385S | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV52209039; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100668423; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100668424; called by muse, mutect2, varscan2
- EFTUD2 | c.2166del p.Y722* | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as COSV99493861; called by pindel, varscan2
- EGFLAM | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as rs750559599, COSV59300471; called by muse, mutect2, varscan2
- EIF2B2 | c.1026A>T p.E342D | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56721568, COSV99837614; called by muse, mutect2, varscan2
- ELAC1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs778285548, COSV53996494; called by mutect2, varscan2
- ELAVL2 | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV56372413; called by muse, mutect2, varscan2
- ELAVL3 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52954498; called by muse, mutect2, varscan2
- ELOA2 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55309959; called by muse, varscan2
- ELOVL1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1489954444, COSV60523250; called by muse, varscan2
- ENAM | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs868759180, COSV68535291; called by muse, mutect2, varscan2
- ENC1 | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV56631626; called by muse, mutect2, varscan2
- ENPEP | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs760638185, COSV54458621; called by muse, mutect2, varscan2
- EPB41L2 | c.2144C>T p.S715L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV61359573; called by mutect2, varscan2
- EPHA6 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1278939329, COSV101065498, COSV67596490; called by muse, mutect2, varscan2
- EPHA7 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV65193240; called by muse, mutect2, varscan2
- EPPK1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV73262462; called by muse, mutect2, varscan2
- EPS8L2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs142895363, COSV59349213; called by mutect2, varscan2
- ERBB4 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV53596395; called by muse, mutect2, varscan2
- ERC2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV55669731; called by muse, mutect2, varscan2
- ERCC6L | c.2747A>G p.E916G | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57822627; called by muse, mutect2, varscan2
- ERICH1 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV100032202, COSV50641599; called by muse, mutect2, varscan2
- ERICH1 | c.1260C>T p.D420= | Splice Region (SNP) | VAF 25/109 reads (23%) | catalogued as COSV100032204; called by muse, mutect2, varscan2
- ESYT1 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as COSV57277024; called by muse, varscan2
- ESYT1 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57277042; called by muse, varscan2
- ETS2 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV62874716; called by muse, mutect2, varscan2
- EYA4 | c.1254G>A p.M418I (on ENST00000531901 / NM_001301013.1; = p.M412I on NM_004100.5) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV62046235; called by mutect2, varscan2
- F13A1 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601094, COSV53569068; called by muse, mutect2, varscan2
- F13B | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201438197, COSV66375940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F13B | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.069); catalogued as rs376931227; called by mutect2, varscan2
- F7 | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as CS025206, COSV60648474; called by muse, mutect2, varscan2
- FAF1 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65644760; called by muse, mutect2, varscan2
- FAM126B | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV53775538; called by muse, mutect2, varscan2
- FAM131C | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV65154425; called by muse, mutect2, varscan2
- FAM135A | c.1996C>T p.P666S (on ENST00000370479 / NM_001351599.1; = p.P453S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52060526; called by muse, mutect2, varscan2
- FAM135B | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52757216; called by muse, mutect2, varscan2
- FAM13A | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1255292181, COSV52014603; called by muse, mutect2, varscan2
- FAM13C | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs143474599; called by muse, mutect2, varscan2
- FAM160B1 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV65087379; called by muse, mutect2, varscan2
- FAM167A | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52705598; called by muse, mutect2, varscan2
- FAM193B | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV61559227; called by muse, mutect2, varscan2
- FAM71B | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57229458; called by muse, mutect2, varscan2
- FAM71C | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990788899, COSV60944648; called by muse, varscan2
- FAM83B | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770948137, COSV60927671; called by muse, mutect2, varscan2
- FANCC | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV56668249; called by muse, mutect2, varscan2
- FAT2 | c.9590C>T p.P3197L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs769750949, COSV55831142; called by muse, mutect2, varscan2
- FAT3 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 182/413 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as COSV53182935; called by muse, mutect2, varscan2
- FAT3 | c.6835G>A p.D2279N | Missense Mutation (SNP) | VAF 202/477 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53182963; called by muse, mutect2, varscan2
- FAT3 | c.8523G>A p.M2841I | Missense Mutation (SNP) | VAF 111/236 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53112086; called by muse, mutect2, varscan2
- FAT4 | c.4367C>T p.S1456F | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV101272018; called by muse, mutect2, varscan2
- FAT4 | c.5132C>T p.A1711V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67902246; called by muse, varscan2
- FAT4 | c.14629G>A p.E4877K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs867911771, COSV58687593; called by muse, mutect2, varscan2
- FBN3 | c.8063G>A p.R2688Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs375603937; called by muse, mutect2, varscan2
- FBXL2 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52143361; called by muse, mutect2, varscan2
- FBXO15 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs758205246, COSV54047043; called by muse, mutect2, varscan2
- FBXO39 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as rs368045455; called by mutect2, varscan2
- FBXO40 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1450325819, COSV57528373; called by muse, mutect2, varscan2
- FCGBP | c.8047G>A p.G2683S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.186); catalogued as rs1325720220; called by muse, mutect2, varscan2
- FCRL5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.013); catalogued as rs1406891065, COSV62512447, COSV62513927; called by muse, mutect2, varscan2
- FECH | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419953421, COSV50493371; called by muse, mutect2, varscan2
- FER1L6 | c.3526C>T p.Q1176* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV67553216; called by muse, mutect2, varscan2
- FGD2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758759895, COSV51466401; called by mutect2, varscan2
- FGFR4 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52801991; called by muse, mutect2, varscan2
- FGGY | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as rs748040209, COSV58047559; called by mutect2, varscan2
- FGL2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50381470; called by muse, mutect2, varscan2
- FIBCD1 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV99446804; called by muse, mutect2, varscan2
- FLG | c.6554G>A p.G2185E | Missense Mutation (SNP) | VAF 94/534 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752353768, COSV64236017; called by muse, mutect2
- FLNA | c.5054C>T p.T1685M (on ENST00000369850 / NM_001110556.2; = p.T1677M on NM_001456.3) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781783107, COSV61052985; called by mutect2, varscan2
- FLNB | c.6886C>T p.Q2296* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55898574; called by mutect2, varscan2
- FLNC | c.7228C>T p.R2410C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs750686083, COSV57966375; called by muse, mutect2, varscan2
- FLT4 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.113); catalogued as rs1410033838, COSV56114866; called by mutect2, varscan2
- FLT4 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56117818, COSV56124518; called by muse, mutect2, varscan2
- FMN2 | c.4237G>A p.E1413K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs768348163, COSV60425877; called by mutect2, varscan2
- FMNL2 | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.239); catalogued as COSV56505885; called by muse, mutect2, varscan2
- FOLH1 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV57057791; called by muse, mutect2, varscan2
- FOLH1 | c.1311G>A p.E437= | Splice Region (SNP) | VAF 17/56 reads (30%) | catalogued as rs571898670, COSV57057199; called by muse, mutect2, varscan2
- FOXB1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101249682; called by muse, mutect2, varscan2
- FOXB1 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101249685; called by mutect2, varscan2
- FOXF2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52527496; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs200522674; called by muse, mutect2, varscan2
- FREM2 | c.8360C>T p.P2787L | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV54854922; called by muse, mutect2, varscan2
- FSHR | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 93/332 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.819); catalogued as COSV58621470; called by muse, mutect2, varscan2
- FSIP1 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs764736214, COSV63227341; called by muse, mutect2, varscan2
- FSIP2 | c.17662G>A p.D5888N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs762359522, COSV58089279; called by muse, mutect2, varscan2
- FSTL1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs773271894, COSV55237633; called by muse, mutect2, varscan2
- GABRA4 | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.239); catalogued as COSV51936282; called by muse, mutect2, varscan2
- GALNT14 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV61102355, COSV61103649; called by muse, mutect2, varscan2
- GALNT6 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV62543553; called by muse, mutect2, varscan2
- GALR1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745422581, COSV55319439; called by muse, mutect2, varscan2
- GATA3 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60516652; called by muse, mutect2, varscan2
- GATB | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV56134048; called by muse, mutect2, varscan2
- GCLC | c.1842A>T p.L614F (on ENST00000643939; = p.L612F on NM_001498.4) | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV57598191; called by muse, mutect2, varscan2
- GET1 | c.435T>A p.F145L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as COSV61555320; called by mutect2, varscan2
- GJA10 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs768451462, COSV65355051; called by muse, varscan2
- GJA10 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV65356515; called by muse, mutect2, varscan2
- GLI2 | c.1294G>A p.D432N (on ENST00000361492 / NM_001374353.1; = p.D449N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs13427953, COSV58044729; called by mutect2, varscan2
- GLRB | c.272T>G p.F91C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100029504; called by muse, mutect2
- GLRB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287910151, COSV52414608; called by muse, varscan2
- GLT1D1 | c.869C>T p.S290F (on ENST00000442111 / NM_001366889.1; = p.S210F on NM_144669.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55877929, COSV55889235; called by muse, mutect2, varscan2
- GMEB1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV53797397; called by muse, mutect2, varscan2
- GOLGA3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52645645; called by muse, mutect2, varscan2
- GP1BA | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV56701047; called by muse, mutect2, varscan2
- GPC5 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV65633075; called by muse, varscan2
- GPN2 | c.320T>G p.F107C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1557657684, COSV64652810; called by muse, varscan2
- GPR158 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.082); catalogued as COSV100892776, COSV66284713; called by muse, mutect2, varscan2
- GPR176 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54444011; called by muse, mutect2, varscan2
- GPRC5A | c.472A>G p.N158D | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.598); catalogued as COSV50008932; called by muse, mutect2, varscan2
- GRIA1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53590724; called by muse, mutect2, varscan2
- GRIA1 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.224); catalogued as COSV53608082, COSV53627746; called by muse, varscan2
- GRIN3A | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62452298, COSV62458577; called by muse, mutect2, varscan2
- GRM3 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473539; called by muse, mutect2, varscan2
- GRM3 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100862181; called by muse, mutect2, varscan2
- GRM3 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100862184, COSV64472485; called by muse, mutect2, varscan2
- GRM3 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs776508668, COSV64473899; called by mutect2, varscan2
- GRM4 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV65220650; called by muse, varscan2
- GRM4 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65220667; called by muse, mutect2, varscan2
- GRM8 | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs758867322, COSV58829885, COSV58875055; called by muse, mutect2, varscan2
- GSX2 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58843658; called by muse, mutect2, varscan2
- GUCY1B1 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52379671; called by muse, mutect2, varscan2
- H2BW1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54221703; called by muse, mutect2, varscan2
- HAO2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV58042590; called by muse, mutect2, varscan2
- HAP1 | c.1589G>A p.R530Q (on ENST00000310778 / NM_001367460.1; = p.R478Q on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/251 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.397); catalogued as rs782302181, COSV57878070; called by muse, mutect2, varscan2
- HAUS1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56363401; called by muse, mutect2, varscan2
- HCN3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100855598; called by muse, varscan2
- HCRTR2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63799587; called by muse, mutect2, varscan2
- HDAC9 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs527740786, COSV67781752; called by mutect2, varscan2
- HDAC9 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV67781348, COSV67783378; called by muse, mutect2, varscan2
- HEATR1 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 112/350 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs1287081321, COSV63983436; called by muse, mutect2, varscan2
- HERC2 | c.8561G>C p.G2854A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55353302; called by muse, mutect2, varscan2
- HHAT | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV54811680; called by muse, mutect2, varscan2
- HHIPL1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58091791; called by muse, varscan2
- HIF3A | c.1936C>T p.P646S (on ENST00000377670 / NM_152795.4; = p.P577S on NM_022462.4) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV54981260; called by muse, mutect2, varscan2
- HIVEP2 | c.6338C>T p.P2113L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV50080042; called by muse, mutect2, varscan2
- HIVEP2 | c.5059A>C p.T1687P | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50080204; called by muse, mutect2, varscan2
- HJURP | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768712893, COSV64979682; called by muse, mutect2
- HK3 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV52845425; called by muse, mutect2, varscan2
- HMCN1 | c.5891C>T p.S1964F | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); catalogued as rs768770768, COSV54946933; called by muse, mutect2, varscan2
- HNF1B | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 371/801 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104565; called by muse, mutect2, varscan2
- HNF4G | c.70T>C p.Y24H (on ENST00000354370 / NM_001330561.2; = p.Y71H on NM_004133.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62974492; called by muse, mutect2, varscan2
- HOXA2 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56067273; called by mutect2, varscan2
- HRNR | c.5780G>A p.G1927E | Missense Mutation (SNP) | VAF 66/703 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV64263548; called by muse, mutect2
- HSD11B1 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV54830386; called by muse, mutect2, varscan2
- HSPB9 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs781869224, COSV56791853, COSV56793229; called by muse, mutect2, varscan2
- HSPBAP1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60241744; called by muse, mutect2, varscan2
- HTR2A | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.184); catalogued as COSV66327040; called by muse, mutect2, varscan2
- HTT | c.7939C>T p.P2647S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as rs1033940913, COSV61859717; called by muse, mutect2, varscan2
- IARS2 | c.2179A>G p.R727G | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56964864; called by muse, mutect2, varscan2
- IBTK | c.2054T>A p.V685D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100090105; called by muse, mutect2, varscan2
- IBTK | c.2053G>A p.V685I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100090109; called by muse, mutect2, varscan2
- ICE1 | c.5039C>T p.A1680V | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56833905; called by muse, varscan2
- IFIT1B | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV65663782; called by muse, mutect2, varscan2
- IFNK | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.606); catalogued as rs1345928409, COSV51791635; called by muse, mutect2, varscan2
- IFNW1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV66522337, COSV66522538; called by muse, mutect2, varscan2
- IGDCC3 | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV60080728; called by muse, mutect2, varscan2
- IGFBP3 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51873674; called by muse, mutect2, varscan2
- IGHV2-26 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs781801011; called by muse, mutect2, varscan2
- IL12A | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.48); catalogued as COSV59760316; called by muse, mutect2, varscan2
- IL1R1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs188550005, COSV52108737; called by muse, mutect2, varscan2
- IL1RL1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs150294315; called by mutect2, varscan2
- IL2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.171); catalogued as COSV56986780; called by muse, mutect2, varscan2
- IL20RA | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV57360934; called by muse, mutect2, varscan2
- IL4R | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as rs1273255220, COSV50138641; called by muse, mutect2, varscan2
- INAVA | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66257738; called by muse, mutect2
- INO80D | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV68960285; called by muse, mutect2
- INPP5D | c.1876G>A p.E626K (on ENST00000445964 / NM_001017915.3; = p.E625K on NM_005541.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.328); catalogued as COSV64040971; called by muse, varscan2
- INSC | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.382); catalogued as COSV65413583; called by muse, mutect2, varscan2
- INSRR | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as rs1397132963, COSV63877816; called by muse, mutect2
- INTS9 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 69/212 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as COSV68436114; called by muse, mutect2, varscan2
- IPO5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.091); catalogued as COSV55160422; called by muse, mutect2, varscan2
- IQCN | c.2984A>C p.H995P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV100828195; called by muse, mutect2
- ITGA7 | c.1807G>A p.G603S (on ENST00000555728; = p.G559S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV57702137; called by muse, mutect2, varscan2
- ITGA8 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.193); catalogued as rs748316674, COSV65226693, COSV65237288; called by muse, mutect2, varscan2
- ITIH2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.051); catalogued as COSV64434422; called by muse, mutect2, varscan2
- ITIH2 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs923997175, COSV64432565; called by muse, mutect2, varscan2
- ITPR2 | c.5803G>A p.E1935K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV67269217; called by muse, mutect2, varscan2
- ITPR2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV67269935; called by muse, varscan2
- ITPRID1 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV60084285; called by muse, mutect2
- IVL | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.159); catalogued as rs777417330, COSV100908120; called by muse, varscan2
- IYD | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV57600068; called by mutect2, varscan2
- IZUMO2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs753806737, COSV53229401, COSV53230185; called by muse, mutect2, varscan2
- JAKMIP1 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51523568, COSV51535873; called by muse, mutect2, varscan2
- KANK4 | c.2195G>A p.G732E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV58094301; called by muse, varscan2
- KAT6A | c.5336C>T p.S1779F | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55903242; called by muse, mutect2, varscan2
- KAT6B | c.5576T>A p.V1859D | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV54755961; called by muse, mutect2, varscan2
- KCNA1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66836419; called by muse, varscan2
- KCNA6 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54977250; called by muse, mutect2, varscan2
- KCNAB1 | c.1150G>A p.E384K (on ENST00000490337 / NM_172160.3; = p.E373K on NM_003471.3) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV56755723; called by muse, mutect2, varscan2
- KCNB2 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs1196389232, COSV73053196; called by muse, mutect2, varscan2
- KCNH7 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59816411; called by muse, mutect2, varscan2
- KCNIP1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61083560; called by mutect2, varscan2
- KCNK1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.199); catalogued as COSV100785883; called by mutect2, varscan2
- KCNK13 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56418445; called by muse, mutect2, varscan2
- KCNN1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs1233681689, COSV55842743; called by muse, mutect2, varscan2
- KCNQ3 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769248820, COSV66483641; ClinVar: uncertain significance; called by mutect2, varscan2
- KCNS2 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.264); catalogued as COSV54641442; called by muse, mutect2, varscan2
- KHDC3L | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1257451545, COSV64859230; called by muse, mutect2, varscan2
- KHDRBS2 | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55468987, COSV55473063; called by muse, varscan2
- KHDRBS2 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV55496738; called by mutect2, varscan2
- KIAA0100 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs1489827272, COSV101197374, COSV66496972; called by muse, mutect2, varscan2
- KIAA0319 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV65501509; called by muse, mutect2, varscan2
- KIAA1549 | c.5741C>T p.S1914F (on ENST00000422774 / NM_001164665.2; = p.S1898F on NM_020910.3) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54331246; called by muse, mutect2, varscan2
- KIF13A | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs770759632, COSV52467724; called by mutect2, varscan2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by mutect2, varscan2
- KIF2C | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs755097249, COSV64764213; called by muse, mutect2, varscan2
- KIR2DL4 | c.794C>T p.P265L (on ENST00000396284; = p.P226L on NM_001080770.2) | Missense Mutation (SNP) | VAF 134/464 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as rs1209045251; called by muse, varscan2
- KIRREL1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63292012; called by muse, mutect2, varscan2
- KITLG | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57200754, COSV57204384; called by muse, varscan2
- KL | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV66310198; called by mutect2, varscan2
- KLF17 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64857180; called by muse, mutect2, varscan2
- KLF3 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as COSV54710278; called by muse, mutect2, varscan2
- KLF7 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58746936; called by muse, mutect2, varscan2
- KLHDC8A | c.606G>A p.W202* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65679457; called by muse, mutect2, varscan2
- KLHL1 | c.1882A>G p.N628D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV64786085; called by muse, mutect2, varscan2
- KLK11 | c.449C>T p.S150L (on ENST00000594768 / NM_144947.3; = p.S118L on NM_006853.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV51576638; called by mutect2, varscan2
- KLK13 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV50067693; called by muse, mutect2, varscan2
- KMT2B | c.4268C>T p.S1423F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV55870750; called by muse, mutect2, varscan2
- KMT2E | c.1293T>A p.Y431* | Nonsense Mutation (SNP) | VAF 49/153 reads (32%) | catalogued as COSV57580863; called by muse, varscan2
- KPRP | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1303958363, COSV64222826; called by muse, varscan2
- KPRP | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); catalogued as COSV64222676; called by muse, varscan2
- KRT1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99358516; called by muse, mutect2, varscan2
- KRT1 | c.1795T>A p.S599T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.191); catalogued as COSV99358517; called by mutect2, varscan2
- KRT13 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 117/264 reads (44%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.665); catalogued as rs768812171, COSV55841013; called by muse, mutect2, varscan2
- KRT24 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.294); catalogued as COSV52882268; called by muse, mutect2, varscan2
- KRT27 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56971284; called by mutect2, varscan2
- KRT33A | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV50367066; called by muse, mutect2, varscan2
- KRT4 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1294012289, COSV53410118; called by muse, mutect2, varscan2
- KRT6C | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs747710925, COSV52876893; called by mutect2, varscan2
- KRT77 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV59241774; called by muse, mutect2, varscan2
- KRT80 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.258); catalogued as rs142483540; called by muse, mutect2, varscan2
- KRTAP13-1 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV62664573; called by muse, mutect2, varscan2
- KRTDAP | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs778599873, COSV58865806; called by mutect2, varscan2
- KSR2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV56685293; called by mutect2, varscan2
- LAMB3 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.714); catalogued as COSV61920246; called by muse, mutect2, varscan2
- LAMC2 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV51460279; called by mutect2, varscan2
- LARP1 | c.1318C>T p.L440F (on ENST00000518297 / NM_033551.3; = p.L363F on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60432000; called by muse, mutect2, varscan2
- LBP | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99460440; called by muse, mutect2, varscan2
- LCA5 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 38/138 reads (28%) | catalogued as COSV63973328; called by mutect2, varscan2
- LCE1B | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as COSV63980745; called by muse, mutect2, varscan2
- LCN9 | c.96G>A p.R32= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as COSV52992453; called by muse, mutect2, varscan2
- LCN9 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs779511345, COSV99479492; called by muse, mutect2, varscan2
- LILRA1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV52181570; called by muse, varscan2
- LILRA1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs1478336067, COSV52185785; called by muse, mutect2, varscan2
- LILRB4 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV54409108; called by muse, varscan2
- LIMS2 | c.229G>A p.G77R (on ENST00000355119 / NM_001161403.3; = p.G101R on NM_017980.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.697); catalogued as COSV55757465; called by muse, mutect2, varscan2
- LINGO1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as COSV62438828; called by muse, mutect2, varscan2
- LIPJ | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV64245845; called by mutect2, varscan2
- LMBRD1 | c.1393T>C p.Y465H (on ENST00000649011; = p.Y443H on NM_018368.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65300388; called by mutect2, varscan2
- LMO1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59959053; called by mutect2, varscan2
- LMOD1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66173497, COSV66174057; called by muse, mutect2, varscan2
- LONP2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53526598; called by muse, mutect2, varscan2
- LONRF2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66540201; called by muse, mutect2, varscan2
- LPA | c.5493G>A p.W1831* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as rs1480015719, COSV60300138; called by muse, mutect2, varscan2
- LPAR1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 71/140 reads (51%) | catalogued as COSV62692119; called by muse, mutect2, varscan2
- LPIN1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99877043; called by muse, mutect2, varscan2
- LPIN1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99877045; called by muse, mutect2, varscan2
- LPIN2 | c.439T>C p.F147L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV55245136; called by muse, mutect2, varscan2
- LRBA | c.4265C>T p.S1422F | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV63953202; called by muse, mutect2, varscan2
- LRP1 | c.10807G>A p.G3603S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1208423392, COSV54528467; called by muse, mutect2, varscan2
- LRP1B | c.11802G>A p.M3934I | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1275734386, COSV67219303, COSV67281460; called by muse, mutect2, varscan2
- LRRC4C | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV53439724; called by mutect2, varscan2
- LRRC4C | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV53439734; called by muse, mutect2, varscan2
- LRRIQ4 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs1392114270, COSV61620427; called by muse, mutect2, varscan2
- LRRIQ4 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs754713329, COSV61618981; called by muse, mutect2, varscan2
- LYST | c.7465C>T p.P2489S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV67715246; called by muse, mutect2, varscan2
- MACF1 | c.17663C>T p.S5888F (on ENST00000372915; = p.S3930F on NM_012090.5) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | catalogued as COSV57148079; called by muse, mutect2, varscan2
- MAD1L1 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV56249866; called by muse, mutect2, varscan2
- MADD | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1309302482, COSV60630284; called by muse, mutect2, varscan2
- MAEL | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.052); catalogued as COSV100901652; called by muse, mutect2, varscan2
- MAGEE2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.099); catalogued as COSV64898092, COSV64898118; called by mutect2, varscan2
- MAMLD1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99475565; called by mutect2, varscan2
- MAN1A2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62975931; called by muse, mutect2, varscan2
- MAPT | c.133+2T>C p.X45_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52248721; called by muse, mutect2, varscan2
- MARCHF3 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV58041226; called by mutect2, varscan2
- MARCO | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs959063380, COSV59059414; called by muse, mutect2, varscan2
- MAST1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs777539503, COSV52256397; called by muse, varscan2
- MB21D2 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV66666435; called by muse, mutect2, varscan2
- MBD3 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50086004; called by muse, mutect2, varscan2
- MCC | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56737450; called by muse, varscan2
- MCHR2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 35/109 reads (32%) | catalogued as rs761446827, COSV56001069; called by muse, varscan2
- MCTP1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.222); catalogued as COSV56513802; called by muse, varscan2
- MCTP1 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs933102624, COSV56529706; called by muse, varscan2
- MCU | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV64064523; called by muse, mutect2, varscan2
- MECOM | c.197A>T p.N66I (on ENST00000468789 / NM_001105078.4; = p.N254I on NM_004991.4) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52971787; called by muse, mutect2, varscan2
- MEF2B | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV50773368; called by muse, varscan2
- MEF2D | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV100560170, COSV61730620; called by muse, mutect2, varscan2
- METTL24 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV58824905; called by muse, varscan2
- METTL2B | c.236A>C p.N79T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52311486; called by muse, mutect2, varscan2
- MGAM | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372197743; called by muse, varscan2
- MGAM | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1554464349, COSV72076058; called by muse, mutect2, varscan2
- MICAL1 | c.2643A>T p.E881D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1431416665, COSV57807340; called by mutect2, varscan2
- MICALL1 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV53243773; called by muse, mutect2, varscan2
- MID2 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs370437496, COSV53311129, COSV53314912; called by muse, mutect2, varscan2
- MISP | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV53122637; called by muse, mutect2
- MKS1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV58306490; called by muse, mutect2, varscan2
- MLF1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766876516, COSV63035442; called by mutect2, varscan2
- MME | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV64708669; called by mutect2, varscan2
- MOGAT3 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV56174873; called by muse, mutect2
- MORC1 | c.2319G>A p.W773* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV51733035; called by muse, mutect2, varscan2
- MPP2 | c.104T>G p.F35C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289965; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, varscan2
- MRGPRX2 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.161); catalogued as COSV61675069; called by muse, mutect2, varscan2
- MRGPRX4 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV58591933; called by muse, mutect2, varscan2
- MROH2B | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.167); catalogued as COSV68190205; called by muse, mutect2, varscan2
- MROH2B | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV68188823; called by muse, mutect2, varscan2
- MRPL20 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV61224693; called by muse, mutect2, varscan2
- MSLN | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV67018993, COSV67021447; called by mutect2, varscan2
- MSR1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs762856785, COSV50518319; called by mutect2, varscan2
- MTFR1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50953446; called by muse, varscan2
- MTHFD2L | c.961C>T p.P321S (on ENST00000395759 / NM_001144978.2; = p.P263S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349612642, COSV57471008; called by muse, mutect2, varscan2
- MTMR4 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV60204418; called by muse, varscan2
- MTMR4 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60204426; called by muse, varscan2
- MUC15 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs267602834, COSV55557730; called by muse, mutect2, varscan2
- MUC16 | c.40642G>A p.D13548N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.989); catalogued as COSV101109650; called by muse, mutect2, varscan2
- MUC16 | c.26174G>A p.R8725K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV67499299; called by muse, mutect2, varscan2
- MUC16 | c.23558C>T p.S7853F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); catalogued as COSV67499308; called by muse, mutect2, varscan2
- MUC16 | c.20317C>T p.P6773S | Missense Mutation (SNP) | VAF 54/231 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.113); catalogued as rs1344397377, COSV67481629; called by muse, mutect2, varscan2
- MUC16 | c.19414G>A p.G6472R | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV67499332; called by muse, mutect2, varscan2
- MUC16 | c.3179G>A p.G1060E | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs148517753, COSV67481929; called by muse, mutect2, varscan2
- MUC17 | c.12666G>A p.M4222I | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs1205378566, COSV60306346; called by muse, mutect2, varscan2
- MUC21 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV66222404; called by muse, varscan2
- MUC3A | c.8270C>T p.P2757L | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as rs528943271, COSV60221599; called by muse, mutect2, varscan2
- MUSK | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs750132076, COSV51896866; called by muse, mutect2, varscan2
- MYF6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV57353771; called by muse, varscan2
- MYH1 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs867278498, COSV56858334; called by muse, mutect2, varscan2
- MYH1 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs267604714; called by muse, mutect2, varscan2
- MYH1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374202732; called by muse, varscan2
- MYH14 | c.5007C>T p.A1669= | Splice Region (SNP) | VAF 8/11 reads (73%) | catalogued as COSV51833453; called by muse, mutect2, varscan2
- MYH4 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV55127641; called by muse, varscan2
- MYH4 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55122787; called by muse, mutect2, varscan2
- MYH7B | c.5800G>A p.E1934K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450496474, COSV52685165, COSV99328576; called by muse, mutect2, varscan2
- MYH8 | c.5546G>A p.R1849Q | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs553671041, COSV67971473; called by muse, mutect2, varscan2
- MYH8 | c.4528+1G>C p.X1510_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as rs556513030, COSV67960013, COSV67962780; called by muse, mutect2, varscan2
- MYL4 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs1385986458, COSV61698801; called by muse, mutect2, varscan2
- MYO1A | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV55657840; called by mutect2, varscan2
- MYO3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56331701; called by muse, mutect2, varscan2
- MYO3B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331334030, COSV58705094; called by muse, mutect2, varscan2
- MYO7B | c.3281A>G p.H1094R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV67352673; called by muse, mutect2, varscan2
- MYOCD | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV58513671; called by muse, mutect2, varscan2
- MYOCD | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58496972; called by muse, mutect2, varscan2
- MYOM1 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs762430543, COSV55291060; called by mutect2, varscan2
- MYT1L | c.2384C>A p.S795Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750013534, COSV101219095; called by mutect2, varscan2
- N4BP2 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as rs1190738681, COSV54707780; called by muse, mutect2, varscan2
- NAALADL2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV70795326; called by muse, mutect2, varscan2
- NAB1 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.678); catalogued as COSV61609523; called by muse, mutect2, varscan2
- NAIF1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV66092722; called by muse, mutect2, varscan2
- NBEAL1 | c.3883G>A p.D1295N | Missense Mutation (SNP) | VAF 170/497 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV71374056; called by muse, mutect2, varscan2
- NCOR2 | c.4325C>T p.A1442V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.31); catalogued as COSV62305793; called by mutect2, varscan2
- NDRG2 | c.1109C>T p.S370F (on ENST00000298687 / NM_001354570.1; = p.S356F on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53873869; called by muse, mutect2, varscan2
- NDRG3 | c.331C>T p.P111S (on ENST00000349004 / NM_032013.4; = p.P99S on NM_022477.4) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV62422065; called by muse, mutect2, varscan2
- NDST4 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52117502; called by muse, mutect2, varscan2
- NEB | c.8332C>T p.P2778S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV51465474; called by muse, mutect2, varscan2
- NEB | c.3640G>A p.E1214K | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs764769462, COSV50885885; called by muse, mutect2, varscan2
- NELL1 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54334235; called by muse, mutect2, varscan2
- NELL2 | c.2405G>A p.G802D | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV61586914; called by muse, mutect2, varscan2
- NEURL3 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV60441048; called by muse, mutect2, varscan2
- NEUROD4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1341073987, COSV54472548; called by muse, mutect2, varscan2
- NFASC | c.230G>A p.R77Q (on ENST00000339876 / NM_001378329.1; = p.R71Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757003214, COSV58365309; called by mutect2, varscan2
- NKAPL | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1306384118, COSV59199239; called by mutect2, varscan2
- NLRC4 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs200929188, COSV61592076; called by muse, mutect2, varscan2
- NLRC5 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV52661967, COSV52664416; called by muse, mutect2, varscan2
- NLRP1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.217); catalogued as rs777859040, COSV52580259; called by muse, mutect2, varscan2
- NLRP10 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV60780006; called by muse, mutect2, varscan2
- NLRP11 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs762382161, COSV64086171; called by mutect2, varscan2
- NLRP5 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66767905; called by muse, mutect2, varscan2
- NLRP7 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs759722627, COSV100051435, COSV60178815; called by muse, mutect2, varscan2
- NLRP8 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV52582840; called by mutect2, varscan2
- NLRP8 | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as COSV52594951; called by muse, mutect2, varscan2
- NLRP9 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100243715, COSV60468486; called by mutect2, varscan2
- NME8 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV52246824; called by muse, mutect2, varscan2
- NOS1 | c.2619T>A p.F873L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV57623293; called by muse, mutect2, varscan2
- NOS1 | c.2529G>A p.R843= | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57622711; called by muse, mutect2, varscan2
- NOTCH4 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV66684434; called by muse, mutect2, varscan2
- NPR1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1286499376, COSV64143912; called by muse, mutect2, varscan2
- NPY5R | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.657); catalogued as COSV58451391; called by muse, mutect2, varscan2
- NRG1 | c.1499C>T p.S500F (on ENST00000405005 / NM_013964.5; = p.S505F on NM_013956.5) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV55178105; called by muse, mutect2, varscan2
- NRK | c.4150C>T p.P1384S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV54605416; called by muse, mutect2, varscan2
- NRSN1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs775560059, COSV65893748, COSV65893763; called by mutect2, varscan2
- NRXN2 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV55464673; called by mutect2, varscan2
- NTRK3 | c.2312G>A p.W771* (on ENST00000360948 / NM_001012338.2; = p.W757* on NM_002530.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 93/143 reads (65%) | catalogued as COSV62317656; called by muse, mutect2, varscan2
- NWD1 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.084); catalogued as COSV60353266; called by muse, mutect2, varscan2
- NYAP2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as COSV56002258; called by muse, mutect2, varscan2
- NYAP2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV56018153; called by muse, mutect2, varscan2
- ODF2 | c.2080A>C p.I694L (on ENST00000434106 / NM_153433.2; = p.I670L on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV63549247; called by muse, mutect2, varscan2
- OGDHL | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs774306809, COSV65105065; called by muse, mutect2, varscan2
- OMA1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV62254749; called by muse, varscan2
- OPRPN | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV68192781; called by muse, mutect2, varscan2
- OR10AG1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267602985, COSV56632145; called by muse, mutect2, varscan2
- OR10J1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs368823977; called by mutect2, varscan2
- OR10J3 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs955185312, COSV59955824; called by muse, varscan2
- OR10K2 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs866682401, COSV59223001; called by muse, mutect2, varscan2
- OR10X1 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV63768104; called by muse, mutect2, varscan2
- OR11L1 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as COSV100869420, COSV63314391; called by muse, mutect2, varscan2
- OR12D3 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV101011211, COSV65830717; called by muse, mutect2, varscan2
- OR13C2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV73377657; called by muse, mutect2, varscan2
- OR13C3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV66166109; called by muse, mutect2, varscan2
- OR13C3 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV66166401; called by muse, mutect2, varscan2
- OR13D1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV59514507, COSV59515171; called by muse, mutect2, varscan2
- OR1J4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); catalogued as COSV61590454; called by muse, mutect2, varscan2
- OR1N1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV59197049; called by muse, mutect2, varscan2
- OR2A42 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV66955860; called by muse, mutect2, varscan2
- OR2C1 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs750064991, COSV59240587; called by muse, mutect2, varscan2
- OR2F1 | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs867092695, COSV101231306, COSV67331678; called by muse, mutect2, varscan2
- OR2F1 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV101231287; called by muse, mutect2, varscan2
- OR2J2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs575458407, COSV65847712, COSV65848471; called by muse, mutect2, varscan2
- OR2J3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.067); catalogued as COSV65848776, COSV65849417; called by muse, mutect2, varscan2
- OR2L3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as COSV100741989, COSV63454825; called by muse, mutect2, varscan2
- OR2V2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201743552, COSV60316667; called by muse, mutect2, varscan2
- OR2W1 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV65851817, COSV65852029; called by muse, mutect2, varscan2
- OR3A2 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68694940, COSV68695332; called by muse, mutect2, varscan2
- OR4A15 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1465313972, COSV59033920, COSV59036784; called by muse, mutect2, varscan2
- OR4B1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs765364031, COSV58883855; called by muse, mutect2, varscan2
- OR4C12 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs1555020127, COSV58860706; called by muse, mutect2, varscan2
- OR4C13 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as rs782767336, COSV73648971; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR51A7 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs746387952, COSV63789081; called by muse, mutect2, varscan2
- OR51E1 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV67809866, COSV67810395; called by muse, mutect2, varscan2
1,268 further variants in this file (542 protein-altering or splice-affecting, 682 silent, 44 other) are not listed here.
